Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7255, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7255-01A (Primary Tumor).

**** Case imported from legacy computer system. The format of this report does not match the original case. ****

**** For cases prior to [REDACTED] the section "SPECIMEN" may have been added. ****

DIAGNOSIS

- (A) RIGHT FACIAL LYMPH NODE:
One node, no tumor present.
- (B) RIGHT HYPOGLOSSAL NODE:
No tumor present.
- (C) LEFT HYPOGLOSSAL NERVE:
Nerve, no tumor present.
- (D) TOTAL GLOSSECTOMY, SUBMANDIBULAR:
THREE FOCI OF INVASIVE MODERATELY WELL DIFFERENTIATED SQUAMOUS
CARCINOMA (SIZE RANGE 6.0 TO 1.2 CM) WITH PERINEURAL
INVASION.
Margins of resection free of tumor.
- (E) LEFT PARAPHARYNGEAL SPACE AND ANTERIOR TONSILLAR PILLAR:
Fibrosis.
- (F) LEFT GINGIVAL NODULE:
No tumor present.
Fibrosis.
- (G) LEFT GINGIVAL NODE:
One node, no tumor present.

COMMENT

The total glossectomy specimen shows three foci of well differentiated squamous carcinoma ranging in size from 6.0 to 1.2 cm, showing a diffuse pattern of invasion to a depth of 0.8 cm.

[REDACTED]

SPECIMEN

- (A) RIGHT FACIAL LYMPH NODE:
- (B) RIGHT HYPOGLOSSAL NODE:
- (C) LEFT HYPOGLOSSAL NERVE:
- (D) TOTAL GLOSSECTOMY, SUBMANDIBULAR:
- (E) LEFT PARAPHARYNGEAL SPACE AND ANTERIOR TONSILLAR PILLAR:
- (F) LEFT GINGIVAL NODULE:
- (G) LEFT GINGIVAL NODE:

SNOMED CODES

T-53000,M-80703

Source: NCI Genomic Data Commons file e5c58500-2eb7-43a1-b774-cc0c94333d1d (TCGA-CV-7255.50842590-95F3-481C-A8BC-AEB9AEDC91A7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).